Somatic mutation profile of tumor specimen TCGA-S9-A6WH-01A (aliquot TCGA-S9-A6WH-01A-12D-A33T-08) from TCGA case TCGA-S9-A6WH, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Mixed glioma; Tissue or organ of origin: Cerebrum; Tumor grade: G2; Age at diagnosis: 73.7 years (26,904 days).
Specimen TCGA-S9-A6WH-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4b2d5d23-97ff-4c2a-9da0-75c01b6741fa.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-S9-A6WH-10A (Blood Derived Normal), aliquot TCGA-S9-A6WH-10A-01D-A33W-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/26ed5122-5cef-45f3-83b9-5af1b68a879b

The open-access MAF lists 70 somatic variants for this specimen: 52 protein-altering or splice-affecting, 15 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 44, Silent 15, Splice Site 2, Nonsense Mutation 2, Intron 2, In Frame Ins 1, Frame Shift Del 1, Frame Shift Ins 1, RNA 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CIC | c.644G>A p.R215Q | Missense Mutation (SNP) | VAF 71/77 reads (92%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1380826096, COSV50546987; called by muse, mutect2, varscan2
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 80/205 reads (39%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ATP13A5 | c.2762T>C p.L921S | Missense Mutation (SNP) | VAF 24/356 reads (7%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as COSV100665562; called by muse, mutect2
- CDC7 | c.1595T>G p.L532* | Nonsense Mutation (SNP) | VAF 18/262 reads (7%) | catalogued as COSV99319882; called by muse, mutect2
- CORO1A | c.1148G>A p.R383Q | Missense Mutation (SNP) | VAF 24/226 reads (11%) | SIFT tolerated (0.43); PolyPhen benign (0.003); catalogued as rs61736366; called by muse, mutect2
- CYLC2 | c.821A>T p.K274M | Missense Mutation (SNP) | VAF 76/186 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.821); catalogued as COSV100872530; called by muse, mutect2, varscan2
- CYP2C9 | c.986G>A p.R329H | Missense Mutation (SNP) | VAF 20/312 reads (6%) | SIFT tolerated (0.27); PolyPhen benign (0.006); catalogued as rs748165211, COSV99583055; called by muse, mutect2
- CYP7A1 | c.1458G>T p.L486F | Missense Mutation (SNP) | VAF 21/128 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.572); catalogued as COSV100052592; called by muse, mutect2, varscan2
- CYSLTR1 | c.290G>A p.R97H | Missense Mutation (SNP) | VAF 17/94 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs199711042, COSV64819755; called by muse, mutect2, varscan2
- CYTH4 | c.1061G>A p.R354H | Missense Mutation (SNP) | VAF 54/122 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.204); catalogued as rs369905837; called by muse, mutect2, varscan2
- DAAM2 | c.1382G>A p.R461H | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.299); catalogued as rs752703893, COSV51337433; called by muse, mutect2, varscan2
- DYNC2H1 | c.6394A>T p.N2132Y | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.093); catalogued as COSV100519446; called by muse, mutect2, varscan2
- EYA1 | c.1531A>G p.K511E | Missense Mutation (SNP) | VAF 10/304 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs1057520766, COSV100380082, COSV58169184; called by muse, mutect2
- GCC2 | c.4431T>A p.N1477K | Missense Mutation (SNP) | VAF 6/92 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.006); catalogued as COSV100565596; called by muse, mutect2
- GGCX | c.2219A>C p.D740A | Missense Mutation (SNP) | VAF 42/109 reads (39%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.015); catalogued as COSV99290134; called by muse, mutect2, varscan2
- GPRASP2 | c.2205G>C p.K735N | Missense Mutation (SNP) | VAF 29/338 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.741); catalogued as COSV59990899; called by muse, mutect2
- HUWE1 | c.1847G>T p.R616L | Missense Mutation (SNP) | VAF 27/99 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV53354299; called by muse, mutect2, varscan2
- IHH | c.979G>A p.G327R | Missense Mutation (SNP) | VAF 4/62 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV99838766; called by muse, mutect2
- LMBRD2 | c.764A>T p.N255I | Missense Mutation (SNP) | VAF 38/98 reads (39%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV99683141; called by muse, mutect2, varscan2
- LYST | c.4754A>G p.N1585S | Missense Mutation (SNP) | VAF 19/410 reads (5%) | SIFT tolerated (0.18); PolyPhen benign (0.404); catalogued as rs1294381222, COSV101090095; called by muse, mutect2
- MAP1A | c.8249A>G p.N2750S | Missense Mutation (SNP) | VAF 6/75 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.965); catalogued as COSV100289073; called by muse, mutect2
- MYH14 | c.4234C>T p.R1412C | Missense Mutation (SNP) | VAF 9/9 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs753656288, COSV51833846; called by muse, mutect2, varscan2
- MYO18A | c.2372C>T p.P791L | Missense Mutation (SNP) | VAF 7/79 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1194995246, COSV100572573; called by muse, mutect2
- NMNAT1 | c.676A>G p.I226V | Missense Mutation (SNP) | VAF 77/89 reads (87%) | SIFT tolerated (0.49); PolyPhen benign (0.309); catalogued as COSV101020441; called by muse, mutect2, varscan2
- NOS1AP | c.460G>A p.A154T | Missense Mutation (SNP) | VAF 9/248 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100723534; called by muse, mutect2
- PASD1 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 8/240 reads (3%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.026); catalogued as COSV100949533, COSV64855005; called by muse, mutect2
- PCCB | c.1389G>A p.M463I | Missense Mutation (SNP) | VAF 29/75 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV99291567; called by muse, mutect2, varscan2
- PDE6A | c.277C>T p.R93C | Missense Mutation (SNP) | VAF 28/133 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.344); catalogued as rs200297339; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PLCH2 | c.3820C>T p.R1274C | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.451); catalogued as rs375251663, COSV99617482; called by muse, mutect2, varscan2
- PRKDC | c.5330T>A p.L1777* | Nonsense Mutation (SNP) | VAF 10/279 reads (4%) | catalogued as COSV100042249; called by muse, mutect2
- RAD54B | c.959G>A p.C320Y | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs757037716, COSV100280104; called by muse, mutect2, varscan2
- RNGTT | c.817C>T p.P273S | Missense Mutation (SNP) | VAF 46/130 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV99667229; called by muse, mutect2, varscan2
- SASH1 | c.3128C>G p.P1043R | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.047); catalogued as rs1035218502, COSV100821382; called by muse, mutect2
- SEC14L1 | c.1611+2T>C p.X537_splice | Splice Site (SNP) | VAF 11/48 reads (23%) | catalogued as COSV101171101, COSV101171153; called by muse, mutect2, varscan2
- SERP2 | c.112G>A p.G38R | Missense Mutation (SNP) | VAF 24/224 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV101002085, COSV64851820; called by muse, mutect2
- SLC52A3 | c.479G>A p.G160D | Missense Mutation (SNP) | VAF 35/140 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99448263; called by muse, mutect2, varscan2
- SLC6A13 | c.1798T>A p.S600T | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT tolerated, low confidence (0.83); PolyPhen benign (0); catalogued as COSV100570034; called by muse, mutect2, varscan2
- SORL1 | c.1781G>A p.S594N | Missense Mutation (SNP) | VAF 30/335 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99495039; called by muse, mutect2
- SPRY3 | c.782G>A p.R261H | Missense Mutation (SNP) | VAF 25/352 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs768085652, COSV100249482; called by muse, mutect2
- SPTBN5 | c.655C>G p.H219D | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.68); catalogued as COSV100312013; called by muse, mutect2, varscan2
- STBD1 | c.157C>T p.H53Y | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.04); catalogued as COSV99421659; called by muse, mutect2
- STBD1 | c.158A>C p.H53P | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated (0.16); PolyPhen benign (0.018); catalogued as COSV99421664; called by muse, mutect2
- SYTL4 | c.1587G>T p.Q529H | Missense Mutation (SNP) | VAF 42/162 reads (26%) | SIFT tolerated (0.46); PolyPhen benign (0.015); catalogued as COSV99343226; called by muse, mutect2, varscan2
- THSD1 | c.121A>G p.T41A | Missense Mutation (SNP) | VAF 30/254 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.338); catalogued as COSV99319022; called by muse, mutect2, varscan2
- TNIK | c.1909C>T p.R637C | Missense Mutation (SNP) | VAF 28/126 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.972); catalogued as rs754231377, COSV52679696; called by muse, mutect2, varscan2
- TNNI3K | c.2134T>A p.F712I | Missense Mutation (SNP) | VAF 11/88 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.875); catalogued as COSV99632113; called by muse, mutect2, varscan2
- UBR4 | c.1018+1G>A p.X340_splice | Splice Site (SNP) | VAF 22/112 reads (20%) | catalogued as COSV100921491; called by muse, mutect2, varscan2
- VDR | c.56A>G p.N19S | Missense Mutation (SNP) | VAF 14/129 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.135); catalogued as rs992960287, COSV99968937; called by muse, mutect2, varscan2
- ZGRF1 | c.1466C>A p.S489Y | Missense Mutation (SNP) | VAF 48/245 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.323); catalogued as COSV100005716; called by muse, mutect2, varscan2
- ARMS2 | c.192_194dup p.S64_M65insI | In Frame Ins (INS) | VAF 79/166 reads (48%) | called by mutect2, pindel, varscan2
- RFX7 | c.1855del p.S619Afs*5 (on ENST00000559447 / NM_001368074.1; = p.S716Afs*5 on NM_022841.7 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 31/155 reads (20%) | called by mutect2, pindel, varscan2
- TCF12 | c.657dup p.M220Yfs*4 | Frame Shift Ins (INS) | VAF 38/263 reads (14%) | called by mutect2, pindel, varscan2
- ACTR2 | c.81T>C p.F27= | Silent (SNP) | VAF 27/266 reads (10%) | catalogued as COSV99574080; called by muse, mutect2, varscan2
- C1orf115 | c.420C>T p.F140= | Silent (SNP) | VAF 17/190 reads (9%) | catalogued as rs762749655, COSV54273872; called by muse, mutect2
- CCT8L2 | c.346C>T p.L116= | Silent (SNP) | VAF 33/86 reads (38%) | catalogued as COSV100743002; called by muse, mutect2, varscan2
- CYP3A5 | c.1116A>G p.R372= | Silent (SNP) | VAF 21/175 reads (12%) | catalogued as rs1021064278, COSV99770007; called by muse, mutect2, varscan2
- OR2T3 | c.495C>T p.T165= | Silent (SNP) | VAF 21/166 reads (13%) | catalogued as rs756312296, COSV100613366; called by muse, mutect2, varscan2
- OR52I1 | c.39T>C p.P13= | Silent (SNP) | VAF 71/439 reads (16%) | catalogued as COSV100331792; called by muse, mutect2, varscan2
- PABPC1L | c.1257A>G p.A419= | Silent (SNP) | VAF 23/129 reads (18%) | catalogued as rs757503898, COSV99408069; called by muse, mutect2, varscan2
- PNMA5 | c.432C>T p.S144= | Silent (SNP) | VAF 37/466 reads (8%) | catalogued as COSV100721694; called by muse, mutect2
- RIMKLA | c.1146C>T p.N382= | Silent (SNP) | VAF 15/168 reads (9%) | catalogued as COSV101290574; called by muse, mutect2
- SCNN1B | c.1881G>A p.P627= | Silent (SNP) | VAF 15/256 reads (6%) | catalogued as rs369141410; called by muse, mutect2
- SERPINB9 | c.1125G>A p.S375= | Silent (SNP) | VAF 49/94 reads (52%) | catalogued as rs376915869; called by muse, mutect2, varscan2
- SLAMF1 | c.564C>A p.A188= | Silent (SNP) | VAF 12/224 reads (5%) | catalogued as COSV99349539; called by muse, mutect2
- SLC25A43 | c.426A>T p.P142= | Silent (SNP) | VAF 24/250 reads (10%) | catalogued as COSV99474683; called by muse, mutect2
- SULT1A2 | c.162G>A p.V54= | Silent (SNP) | VAF 14/206 reads (7%) | catalogued as rs559578354, COSV57681896; called by muse, mutect2
- TMEM201 | c.748C>T p.L250= | Silent (SNP) | VAF 13/40 reads (33%) | catalogued as COSV100440579; called by muse, mutect2, varscan2
- AC245047.1 | n.102A>G | RNA (SNP) | VAF 35/421 reads (8%) | called by muse, mutect2
- EIF4A2 | c.771+202A>C | Intron (SNP) | VAF 14/147 reads (10%) | catalogued as COSV99961321; called by muse, mutect2, varscan2
- TTN | c.10360+2192T>C | Intron (SNP) | VAF 47/265 reads (18%) | catalogued as COSV100624754; called by muse, mutect2, varscan2
